Somatic mutation profile of tumor specimen TARGET-30-PATXHC-01A (aliquot TARGET-30-PATXHC-01A-01D) from TARGET case TARGET-30-PATXHC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.4 years (1,600 days).
Specimen TARGET-30-PATXHC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0d470dc-0e41-4d90-9c0e-8e1fbf2efa31.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATXHC-10A (Blood Derived Normal), aliquot TARGET-30-PATXHC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/208e3f58-1ba9-4fde-bd10-37539ca244b2

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- TAF1L | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 15/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244920150; called by muse, mutect2
